Surgical pathology report (de-identified scan), TCGA case TCGA-V4-A9EM, project TCGA-UVM (Uveal Melanoma), tissue source site Institut Curie, specimen TCGA-V4-A9EM-01A (Primary Tumor).

Date of surgery :

Left eye enucleation

Macroscopy

The eye ball measures 28 by 20 mm and presents a posterior segment of optic nerves measuring 7 mm. At the section, the tumor measures 17 mm main line. Samples have been frozen for genetic studies then the piece has been fixed and included entirely.

Microcopy

The tumor observed macroscopically corresponds to an uveal melanoma, mainly composed of epithelioid cells. The cell cytoplasm is often pigmented with melanin. The nuclear atypia are severe. The mitotic index is low (4 mitoses for 10 HPF).

The tumor is developed close to the ciliary body and infiltrates the internal part of the sclera, leaving the half external part free. It is located at a large distance of the optic foramen and the optic nerve on its entire course and cut end is free of tumor.

The meningeal sheets and the extra-scleral tissues are free of tumor.

Conclusion

Uveal melanoma of the left eye.

Epithelioid cells predominant

Size of the tumor: 17 mm.

Infiltration of the internal half part of the sclera without extrascleral extension.

No intra-vascular tumor embolisms.

The optic nerve on its entire course, its cut end and the meningeal sheets are free of tumor.

ICD-O-3

Melanoma, epithelioid cell
Site Choroid
with
Ileal tract
W 3/10/14

Case ID	12/30/13	Yes	No
Diagnosis			
Primary Tumor Site			
ICD-O-3			
Other Tumor History			
Qual/Synchro in Primary Note			
Case ID	12/30/13	DISQUALIFIED	

Source: NCI Genomic Data Commons file 5ce0bd35-fcdc-4fb1-bcd9-ed349b7000bc (TCGA-V4-A9EM.3EA19BCF-5CE1-4C19-9C21-BEE6D9E45C74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).